Gene-level copy-number profile of tumor specimen TCGA-P3-A6T3-01A from TCGA case TCGA-P3-A6T3, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 49.7 years (18,143 days).
Specimen TCGA-P3-A6T3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.52b09a49-1718-4efb-a6e5-264c58e4572d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-P3-A6T3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d9dfded1-7454-47e1-8fde-22c8dc68a85a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 844; copy number 2: 12,170; copy number 3: 25,347; copy number 4: 14,580; copy number 5: 3,886; copy number 6: 2,666; copy number 9: 244; copy number 12: 8; copy number 16: 22; copy number 24: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-P3-A6T3-01A-11D-A34I-01): tumor purity 0.55, ploidy 3.34, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 317 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:68,870,664–78,215,232, 316 genes, copy number 9–24 (broad region; genes not listed).
- chr11:78,223,815–78,225,909, 1 gene, copy number 9: AP002985.1.

Autosomal genes at a single copy (total copy number 1): 275. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
